Gene-level copy-number profile of tumor specimen HCM-BROD-0047-C71-02A from HCMI case HCM-BROD-0047-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 61.3 years (22,404 days).
Specimen HCM-BROD-0047-C71-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d392c02e-a06c-49ad-ad52-8212b6a99060.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0047-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/11f2e917-13cf-430a-9297-2c4bd754f5da

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 123; copy number 1: 20,337; copy number 2: 33,835; copy number 3: 4,608; copy number 4: 13.

Homozygous deletions (total copy number 0; autosomes only): 123 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:133,871,246–135,371,924, 13 genes: AC079380.1, AC015631.1, PABPC4L, PES1P1, LINC02462, AC093722.1, AC104619.2, AC104619.4, AC104619.1, AC104619.3, AC107463.1, LINC02485, KRT18P54.
- chr5:164,935,162–164,935,268, 1 gene (within-gene range 0–2): RNU6-209P.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr8:139,727,725–140,638,283, 11 genes: TRAPPC9, AC021744.1, C8orf17, AC040978.1, PEG13, AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD.
- chr9:19,789,179–19,967,994, 5 genes: AL158077.2, AL158077.1, AL591222.1, AL591222.2, AL591222.3.
- chr9:21,077,104–23,438,700, 58 genes: IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr15:21,307,749–21,307,855, 1 gene: RNU6-1235P.
- chr18:79,340,258–79,343,972, 1 gene (within-gene range 0–1): AC023090.1.
- chr21:7,744,962–8,701,562, 29 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 17,481. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
